Somatic mutation profile of tumor specimen MP2PRT-PARISW-TMP1-A (aliquot MP2PRT-PARISW-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARISW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,180 days).
Specimen MP2PRT-PARISW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c135e108-3a9d-4542-befc-6b7032c6f641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARISW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARISW-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72a5827b-6b68-46b3-a1f1-93df59271669

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11A1 | c.1295C>A p.P432Q | Missense Mutation (SNP) | VAF 203/505 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51432037, COSV51432652; called by muse, mutect2, varscan2
- DHRS2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as rs143433482; called by muse, mutect2, varscan2
- ELMO3 | c.1783C>T p.R595C (on ENST00000652269; = p.R542C on NM_024712.5) | Missense Mutation (SNP) | VAF 223/498 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as rs376215282; called by muse, mutect2, varscan2
- IRF7 | c.830C>T p.P277L (on ENST00000397566; = p.P264L on NM_001572.5) | Missense Mutation (SNP) | VAF 247/657 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768173551, COSV52751960; called by muse, mutect2, varscan2
- KMT2D | c.14815G>A p.E4939K | Missense Mutation (SNP) | VAF 241/706 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.365); catalogued as rs569620684, COSV56503708; called by muse, mutect2, varscan2
- P2RY14 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 120/536 reads (22%) | catalogued as rs187659532; called by muse, mutect2, varscan2
- TMC2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as rs758426455, COSV62651174; called by muse, mutect2, varscan2
- AKT1 | c.1081A>C p.I361L | Missense Mutation (SNP) | VAF 243/631 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ATG2B | c.4993C>A p.L1665M | Missense Mutation (SNP) | VAF 119/347 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CDC42BPB | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 189/454 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTSC | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 15/496 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- DDX4 | c.1976T>A p.V659E | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DHX9 | c.3238C>T p.Q1080* | Nonsense Mutation (SNP) | VAF 101/266 reads (38%) | called by muse, mutect2, varscan2
- FAT2 | c.8363G>C p.G2788A | Missense Mutation (SNP) | VAF 194/518 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- IGKV1-16 | c.351del p.P117del | Frame Shift Del (DEL) | VAF 61/101 reads (60%) | called by mutect2, pindel*, varscan2
- MAD1L1 | c.1470_1471insCT p.F491Lfs*14 | Frame Shift Ins (INS) | VAF 157/515 reads (30%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.641_642insG p.D214Efs*3 | Frame Shift Ins (INS) | VAF 168/540 reads (31%) | called by mutect2, pindel, varscan2
- PRMT3 | c.74C>G p.S25W | Missense Mutation (SNP) | VAF 230/659 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, varscan2
- RFX6 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 77/546 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC45A4 | c.517G>A p.D173N (on ENST00000517878 / NM_001286646.2; = p.D122N on NM_001080431.2) | Missense Mutation (SNP) | VAF 50/854 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM259 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 310/830 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC28 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 82/513 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XYLT1 | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 242/670 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH12 | c.369T>C p.P123= | Silent (SNP) | VAF 156/468 reads (33%) | called by muse, mutect2, varscan2
- CPA5 | c.45C>T p.P15= | Silent (SNP) | VAF 189/503 reads (38%) | catalogued as rs781973473; called by muse, mutect2, varscan2
- DHX9 | c.3237G>C p.G1079= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as rs761875075; called by muse, mutect2, varscan2
- FAM98C | c.168C>G p.L56= | Silent (SNP) | VAF 335/956 reads (35%) | called by muse, mutect2, varscan2
- KL | c.2251A>C p.R751= | Silent (SNP) | VAF 205/530 reads (39%) | called by muse, mutect2, varscan2
- KLF13 | c.552C>G p.L184= | Silent (SNP) | VAF 248/671 reads (37%) | catalogued as rs553114301, COSV56147453, COSV56148124; called by muse, mutect2, varscan2
- RASIP1 | c.1719C>G p.L573= | Silent (SNP) | VAF 320/864 reads (37%) | called by muse, mutect2, varscan2
- ZFPM1 | c.1359C>T p.S453= | Silent (SNP) | VAF 270/679 reads (40%) | catalogued as rs765782820; called by mutect2, varscan2
- CPLANE1 | c.*2704C>T | 3'UTR (SNP) | VAF 173/459 reads (38%) | catalogued as rs750256343; called by muse, mutect2, varscan2
- GRAMD1B | c.374+941_374+942delinsTCCCTCG | Intron (INS) | VAF 91/351 reads (26%) | called by pindel, varscan2*
